Somatic mutation profile of tumor specimen TCGA-N6-A4V9-01A (aliquot TCGA-N6-A4V9-01A-11D-A28R-08) from TCGA case TCGA-N6-A4V9, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Age at diagnosis: 59.3 years (21,677 days).
Specimen TCGA-N6-A4V9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 742cc84d-9240-4698-a061-9c3c558a5a48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N6-A4V9-10A (Blood Derived Normal), aliquot TCGA-N6-A4V9-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57e607fb-bbf9-4a37-bd2b-70680f2a358e

The open-access MAF lists 44 somatic variants for this specimen: 35 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 8, Nonsense Mutation 4, Frame Shift Del 2, Translation Start Site 1, 3'UTR 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 17/26 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 44/46 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AREG | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52644521; called by muse, mutect2, varscan2
- ASH2L | c.1719G>A p.T573= | Splice Region (SNP) | VAF 12/42 reads (29%) | catalogued as rs763735586, COSV51699630; called by muse, mutect2
- CIBAR2 | c.214G>C p.A72P | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73320643; called by muse, mutect2, varscan2
- CYB5D2 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs754761381; called by muse, mutect2, varscan2
- DLGAP2 | c.2317G>A p.V773I | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs34274599, COSV70097003; called by muse, mutect2, varscan2
- FBXO30 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 111/220 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764531233, COSV52792710; called by muse, mutect2, varscan2
- MRPL11 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60599430; called by muse, mutect2, varscan2
- NCDN | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 123/132 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs141726468; called by muse, mutect2, varscan2
- NME1 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs1380078411; called by muse, mutect2, varscan2
- PLCL2 | c.672G>T p.E224D (on ENST00000615277 / NM_001144382.2; = p.E98D on NM_015184.5) | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV67625821; called by muse, mutect2, varscan2
- SCN2B | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs772817742; called by muse, mutect2, varscan2
- SLC10A5 | c.380A>G p.K127R | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs762298410; called by muse, mutect2
- SOX6 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 91/97 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769385306, COSV57035700; called by muse, mutect2, varscan2
- SPDYE3 | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 22/33 reads (67%) | catalogued as rs1288202245; called by mutect2, varscan2
- TRPV4 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99924568; called by muse, mutect2, varscan2
- CD300A | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- CENPE | c.313G>T p.V105F | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CEP70 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- CLTC | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.253); called by muse, varscan2
- FAM102B | c.929T>A p.I310K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LGR5 | c.347T>A p.L116H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- LGR5 | c.351del p.V118Ffs*9 | Frame Shift Del (DEL) | VAF 8/75 reads (11%) | called by mutect2, pindel, varscan2
- LYZL2 | c.496A>G p.T166A (on ENST00000375318; = p.T120A on NM_183058.3) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2
- PLCXD3 | c.261G>T p.Q87H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- POTEA | c.125A>T p.N42I | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2
- RASGRF2 | c.1638_1639del p.F547Wfs*6 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | called by pindel, varscan2
- RXYLT1 | c.107C>G p.P36R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.132); called by muse, varscan2
- SCN3A | c.3786T>A p.Y1262* | Nonsense Mutation (SNP) | VAF 121/242 reads (50%) | called by muse, mutect2, varscan2
- SLIT1 | c.4409T>C p.V1470A | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT tolerated (0.72); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SOWAHA | c.1529C>A p.P510H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAT3 | c.551-1del p.X184_splice | Splice Site (DEL) | VAF 21/29 reads (72%) | called by mutect2, pindel, varscan2
- TNMD | c.431A>G p.E144G | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- TULP4 | c.2698G>T p.V900L | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ABCA13 | c.11010A>G p.A3670= | Silent (SNP) | VAF 93/197 reads (47%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.1095C>T p.F365= | Silent (SNP) | VAF 67/72 reads (93%) | catalogued as COSV52848496; called by muse, mutect2, varscan2
- DAB2 | c.1566T>C p.N522= | Silent (SNP) | VAF 60/129 reads (47%) | called by muse, mutect2, varscan2
- FASN | c.5997C>A p.T1999= | Silent (SNP) | VAF 19/85 reads (22%) | called by muse, mutect2, varscan2
- GABRA6 | c.1176G>T p.T392= | Silent (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2
- GRM3 | c.1977G>A p.L659= | Silent (SNP) | VAF 104/198 reads (53%) | called by muse, mutect2, varscan2
- NPAS4 | c.1338C>G p.T446= | Silent (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- UBA2 | c.762T>C p.L254= | Silent (SNP) | VAF 37/71 reads (52%) | called by muse, mutect2, varscan2
- LARS2 | c.*831A>T | 3'UTR (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
